Gene-level copy-number profile of tumor specimen TARGET-40-PALHRL-01A from TARGET case TARGET-40-PALHRL, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.5 years (6,019 days).
Specimen TARGET-40-PALHRL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.b1e82ea6-0f9b-59da-95c5-1913a60d63d7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PALHRL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 374 have no estimate.
https://portal.gdc.cancer.gov/files/65cfd03f-9d26-42f0-833e-89e28846131a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 569; copy number 1: 2,237; copy number 2: 8,793; copy number 3: 26,576; copy number 4: 18,204; copy number 5: 1,643; copy number 6: 1,188; copy number 7: 228; copy number 8: 125; copy number 9: 103; copy number 10: 61; copy number 11: 13; copy number 12: 50; copy number 13: 1; copy number 15: 3; copy number 17: 1; copy number 18: 2; copy number 20: 7; copy number 22: 159; copy number 24: 66; copy number 25: 51; copy number 27: 16; copy number 28: 37; copy number 29: 15; copy number 34: 20; copy number 36: 5; copy number 37: 17; copy number 38: 14; copy number 39: 11; copy number 40: 8; copy number 43: 1; copy number 46: 25.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr3:116,645,902–117,027,039, 8 genes: BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr5:166,028,567–166,029,311, 1 gene: RPL7P20.
- chr10:17,137,336–17,202,054, 2 genes (within-gene range 0–2): AC067747.1, TRDMT1.
- chr10:124,917,143–124,988,189, 3 genes: AL731577.2, ZRANB1, AL731577.1.
- chr10:124,996,064–125,032,870, 2 genes: AL731571.1, MIR4296.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,021 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,173,049–150,913,292, 38 genes, copy number 9: AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51.
- chr1:172,366,540–172,366,646, 1 gene, copy number 9: RNU6-157P.
- chr2:39,786,453–42,425,088, 21 genes, copy number 8 (within-gene range 6–8): SLC8A1-AS1, AC007253.1, SLC8A1, AC007877.1, AC007317.1, AC007317.2, LINC01794, HNRNPA1P57, AC009413.1, LDHAP3, RPS12P4, Y_RNA, LINC01913, RNU4-63P, LINC01914, C2orf91, AC013480.1, PKDCC, EML4-AS1, EML4, COX7A2L.
- chr2:79,185,231–80,648,861, 1 gene, copy number 8 (within-gene range 4–8): CTNNA2.
- chr2:79,492,704–81,201,184, 12 genes, copy number 8: CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1.
- chr2:83,522,814–83,657,842, 3 genes, copy number 8: LINC01809, RPL37P10, RNU6-1312P.
- chr2:84,750,769–85,668,741, 44 genes, copy number 7: DUXAP1, LDHAP7, TRABD2A, AC010087.1, RPL12P18, TMSB10, RPS2P17, AC022210.1, KCMF1, LINC01964, AC078974.1, LSM3P3, TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, PARTICL, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB.
- chr2:176,809,426–176,809,859, 1 gene, copy number 7: AC092162.1.
- chr3:178,164,008–178,385,479, 1 gene, copy number 7 (within-gene range 4–7): AC117453.1.
- chr3:178,429,197–178,429,290, 1 gene, copy number 7: RNA5SP148.
- chr3:189,956,728–190,449,876, 8 genes, copy number 7: P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207.
- chr3:194,584,004–196,027,694, 52 genes, copy number 8: TMEM44-AS1, TMEM44, AC046143.1, AC046143.2, LSG1, FAM43A, AC106706.1, AC106706.2, LINC01968, AC090505.1, LINC01972, AC090505.2, XXYLT1, XXYLT1-AS1, MIR3137, RN7SL36P, XXYLT1-AS2, RNU6-25P, AC090018.2, ACAP2, ACAP2-IT1, AC090018.1, Y_RNA, PPP1R2, RNU6ATAC24P, AC069213.1, RN7SL73P, AC069213.3, AC069213.2, APOD, MUC20P1, AC233280.36, AC233280.2, AC233280.1, MUC20-OT1, SDHAP2, MIR570, SMBD1P, MUC20, MUC4, LINC01983, KIF3AP1, TNK2, MIR6829, AC124944.3, TNK2-AS1, AC124944.2, RNU2-11P, AC124944.1, SDHAP1, AC024937.3, AC024937.2.
- chr3:196,044,695–196,045,254, 1 gene, copy number 8: AC024937.1.
- chr4:6,763,508–8,619,761, 36 genes, copy number 7: AC106045.1, KIAA0232, TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1, LINC02447, RN7SKP36, SORCS2, MIR4798, PSAPL1, MIR4274, AFAP1-AS1, AFAP1, AC112254.1, AC097381.1, ABLIM2, MIR95, AC097381.3, AC097381.2, GMPSP1, SH3TC1, HTRA3, LINC02517, AC104825.1, ACOX3, RNA5SP152, TRMT44, AC105345.2, AC105345.1, GPR78, CPZ.
- chr4:14,909,961–15,070,153, 2 genes, copy number 7: CPEB2-DT, CPEB2.
- chr4:15,093,767–15,094,094, 1 gene, copy number 7: RN7SKP170.
- chr4:19,455,418–20,620,561, 7 genes, copy number 7–10: AC024230.1, AC110767.1, AC114728.1, AC098862.1, SLIT2, SLIT2-IT1, MIR218-1.
- chr4:22,345,071–25,030,946, 22 genes, copy number 7–9: ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6, AC097512.1, AC092440.1, RFPL4AP3, AC093607.1, ERVH-1, PPARGC1A, AC092834.1, DHX15, MIR573, RN7SL16P, ATP5MGP3, LINC02473, AC006390.1, HNRNPA1P65, SOD3, CCDC149, LGI2.
- chr4:27,917,753–28,600,845, 6 genes, copy number 8: AC007106.2, AC007106.1, AC093791.2, AC093791.1, AC097480.1, AC097480.2.
- chr4:30,718,805–32,745,525, 11 genes, copy number 8–15: AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, AC116611.1.
- chr4:38,509,767–39,399,248, 19 genes, copy number 8: LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3, RNA5SP158, TLR10, TLR1, TLR6, FAM114A1, MIR574, TMEM156, KLHL5, AC079921.1, AC079921.2, WDR19, RFC1, RNU6-32P, RNU6-887P.
- chr4:40,810,027–41,216,714, 1 gene, copy number 7 (within-gene range 6–7): APBB2.
- chr4:40,990,154–42,657,105, 30 genes, copy number 7 (within-gene range 5–7): RNA5SP160, RNU6-836P, RNU6-1195P, UCHL1-AS1, UCHL1, Y_RNA, LIMCH1, RPL12P20, AC108050.1, AC105389.2, OR5M14P, PHOX2B, PHOX2B-AS1, AC105389.1, RNU1-49P, HMGB1P28, LINC00682, AC108210.1, AC108210.2, TMEM33, DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7.
- chr4:44,622,065–45,480,136, 12 genes, copy number 7 (within-gene range 5–7): YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1, RNU6-931P.
- chr4:75,724,577–78,544,269, 57 genes, copy number 10 (within-gene range 6–10): USO1, AC110615.1, RNU2-16P, PPEF2, NAAA, SDAD1, SDAD1-AS1, CXCL9, ART3, CXCL10, CXCL11, AC112719.1, NUP54, AC110795.1, SCARB2, FAM47E, AC034139.1, FAM47E-STBD1, STBD1, CCDC158, SNX5P1, RNU6-1000P, AC096743.2, AC096743.1, SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P, CCNG2, AC008638.3, AC008638.2, AC008638.1, AC092674.1, CXCL13, AC104701.1, CNOT6L, MRPL1, AC112225.1, AC114801.2, HMGB1P44, HNRNPA1P56, AC114801.1, AC114801.3, FRAS1, SERBP1P5.
- chr4:80,335,730–80,963,750, 1 gene, copy number 9 (within-gene range 6–11): CFAP299.
- chr4:81,030,708–83,605,875, 53 genes, copy number 9 (within-gene range 6–9): BMP3, PRKG2, PRKG2-AS1, RNU5A-2P, RASGEF1B, MTCYBP44, COX5BP1, AC021863.1, NPM1P41, HNRNPA3P13, RNU6-499P, BIN2P1, VAMP9P, AC124016.2, HNRNPD, AC124016.1, IGBP1P4, SNORD42, HNRNPDL, ENOPH1, TMEM150C, RPL7AP26, AC067942.1, AC067942.3, AC067942.2, LINC00575, AC067942.4, SCD5, AC073413.1, MIR575, AC073413.2, SEC31A, THAP9-AS1, THAP9, LIN54, Y_RNA, RNU6-615P, COPS4, AC073840.1, PLAC8, AC114781.2, AC114781.3, AC114781.1, COQ2, HPSE, AC114781.5, AC114781.4, HELQ, MRPS18C, ABRAXAS1, SLC25A14P1, RPL30P5, GPAT3.
- chr6:38,565,950–39,030,792, 8 genes, copy number 11 (within-gene range 4–11): Y_RNA, AL079341.1, GLO1, AL391415.1, DNAH8, RN7SL465P, AL035555.2, AL035555.1.
- chr6:39,329,990–39,725,408, 4 genes, copy number 11 (within-gene range 4–11): KIF6, AL136087.1, E2F4P1, RNU1-54P.
- chr6:121,542,486–121,654,690, 4 genes, copy number 8: RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7.
- chr8:14,309,033–15,967,950, 13 genes, copy number 7–24 (within-gene range 5–24): EIF4EP5, RNU7-153P, Y_RNA, RNU6-397P, AC040926.1, MIR383, AC084838.1, AC103851.1, TUSC3, AC100850.1, PPM1AP1, AC018437.3, AC018437.1.
- chr10:47,689,707–49,115,522, 32 genes, copy number 7 (within-gene range 5–7): SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP, FRMPD2, AC074325.1, RPS6P14, MAPK8, AC016397.2, ARHGAP22, ARHGAP22-IT1, AC016397.1, AC068898.2, AC068898.1, WDFY4, RPL13AP19, AC035139.2, AC035139.1, AC060234.3, LRRC18, AC060234.2, AC060234.1, MIR4294, VSTM4.
- chr10:51,062,579–51,068,553, 1 gene, copy number 8: AL731537.1.
- chr10:133,430,394–133,569,835, 7 genes, copy number 7: OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1.
- chr17:7,686,071–10,623,886, 100 genes, copy number 25–39 (within-gene range 4–39) (broad region; genes not listed).
- chr17:11,598,470–11,969,748, 1 gene, copy number 13 (within-gene range 3–13): DNAH9.
- chr17:12,917,268–18,736,118, 221 genes, copy number 12–28 (broad region; genes not listed).
- chr19:27,638,483–32,244,083, 87 genes, copy number 27–46 (broad region; genes not listed).
- chr19:39,685,244–41,307,787, 82 genes, copy number 22–29 (broad region; genes not listed).
- chr20:31,440,632–31,723,989, 17 genes, copy number 7: DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.

Autosomal genes at a single copy (total copy number 1): 583. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
